Somatic mutation profile of tumor specimen MMRF_1089_1_BM_CD138pos (aliquot MMRF_1089_1_BM_CD138pos_T1_KAS5U_L00690) from MMRF case MMRF_1089, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,405 days).
Specimen MMRF_1089_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fec206e-7e82-4179-a347-e141fec077fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1089_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1089_1_PB_Whole_C2_KAS5U_L00698; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/539e86a9-b020-41e4-9e25-3d63b811ea66

The open-access MAF lists 160 somatic variants for this specimen: 66 protein-altering or splice-affecting, 26 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 31, Silent 26, Intron 18, 5'UTR 9, 5'Flank 4, 3'Flank 3, RNA 3, Frame Shift Del 2, Splice Region 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>A p.G636S (on ENST00000288602 / NM_001374244.1; = p.G596S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic; called by muse, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 42/53 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTG1 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as rs782520261; called by muse, mutect2, varscan2
- ACTN2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs201335965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP12 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1376658840; called by muse, mutect2, varscan2
- ASL | c.656-4C>A | Splice Region (SNP) | VAF 34/110 reads (31%) | catalogued as rs571362354; called by muse, mutect2, varscan2
- CAMTA2 | c.2407G>A p.V803M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1400418727, COSV99236298; called by muse, mutect2, varscan2
- CCDC61 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs922291646; called by muse, mutect2, varscan2
- CCT7 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1456527525; called by muse, mutect2
- CNGA2 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1183569188; called by muse, mutect2, varscan2
- COL20A1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.349); catalogued as rs202110157; called by muse, mutect2, varscan2
- COL7A1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760414178, COSV60391564; called by muse, mutect2, varscan2
- DUSP2 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1355569559; called by muse, mutect2, varscan2
- FNBP1 | c.6C>G p.S2R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV63087931; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs370193821; called by muse, varscan2
- IGHV2-70D | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1466061529; called by muse, varscan2
- IGHV3-30 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.022); catalogued as rs753758174; called by muse, mutect2, varscan2
- IGLL5 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.456); catalogued as rs773694665, COSV101597228; called by muse, varscan2
- IGLV3-1 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs543686482; called by muse, varscan2
- IGLV3-1 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs533329143; called by muse, varscan2
- IGLV3-1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs529856363; called by muse, varscan2
- INSR | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as CD016174; called by muse, mutect2, varscan2
- JRK | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs373016139; called by muse, mutect2, varscan2
- MID1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1169366982, COSV58198773; called by muse, mutect2, varscan2
- NEU4 | c.548G>A p.R183H (on ENST00000391969 / NM_001167602.3; = p.R195H on NM_080741.4) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as rs200811936, COSV57991613; called by muse, mutect2, varscan2
- NPFFR2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs370639476; called by muse, mutect2, varscan2
- NRK | c.1205A>C p.Q402P | Missense Mutation (SNP) | VAF 45/46 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54601301; called by muse, mutect2, varscan2
- NSL1 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV65325997; called by muse, mutect2, varscan2
- PCDHGA11 | c.1930G>A p.V644M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs527921011; called by muse, mutect2, varscan2
- PLCH1 | c.3883G>A p.A1295T (on ENST00000340059 / NM_001130960.2; = p.A1287T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100396680; called by muse, mutect2, varscan2
- PRSS1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV61192476, COSV61193173; called by muse, mutect2, varscan2
- RP1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as rs1314264852; called by muse, mutect2, varscan2
- TMCC2 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772092698, COSV58006473; called by muse, mutect2, varscan2
- USH2A | c.5728C>T p.Q1910* | Nonsense Mutation (SNP) | VAF 46/81 reads (57%) | catalogued as CM155002; called by muse, mutect2, varscan2
- XIRP1 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1008901870; called by muse, mutect2, varscan2
- ZNF43 | c.517del p.L173Ffs*17 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV100731789; called by mutect2, pindel, varscan2
- ABLIM1 | c.862T>C p.C288R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APC | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMC8 | c.1421_1427del p.C474* (on ENST00000469044 / NM_001363941.2; = p.C460* on NM_015396.6) | Frame Shift Del (DEL) | VAF 24/39 reads (62%) | called by mutect2, varscan2
- CARS1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIC4 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL16A1 | c.4292G>C p.G1431A | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- COL4A1 | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COPE | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- DAB2IP | c.275G>A p.S92N (on ENST00000408936; = p.S64N on NM_032552.3) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- DLD | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 95/131 reads (73%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGF2R | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IGHV2-70D | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, varscan2
- IGLV3-1 | c.317G>C p.C106S | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- KRTAP19-7 | c.44_73del p.C15_G24del | In Frame Del (DEL) | VAF 12/172 reads (7%) | called by mutect2, pindel
- KSR2 | c.2567A>G p.D856G | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMNB2 | c.1385T>A p.F462Y | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, varscan2
- MGMT | c.218+5G>A | Splice Region (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- MUC5AC | c.16523C>T p.A5508V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- NPHS1 | c.1207A>T p.T403S | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NXF1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ONECUT2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OXR1 | c.647A>C p.K216T (on ENST00000442977 / NM_001198532.1; = p.K215T on NM_018002.3) | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCA | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RELN | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.20A>C p.N7T | Missense Mutation (SNP) | VAF 76/108 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV5-3 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- VGF | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF17 | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.1557A>C p.T519= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- ANKRD17 | c.7224G>T p.P2408= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- ATM | c.6696G>A p.E2232= | Silent (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- CASP9 | c.672C>T p.H224= | Silent (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- CD2AP | c.1770T>C p.I590= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- CHD2 | c.2892T>C p.N964= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- CHST3 | c.492G>A p.P164= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs775338973, COSV64150296; called by muse, mutect2, varscan2
- CPT1C | c.1707C>T p.I569= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs139121663; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCAF5 | c.1776G>A p.K592= | Silent (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- EP400 | c.1629C>T p.P543= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs756748862, COSV57772391; called by muse, mutect2, varscan2
- GPR180 | c.1146C>T p.S382= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1407805518; called by muse, mutect2
- H3C2 | c.381C>T p.L127= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as rs1348013874, COSV52519556; called by muse, mutect2, varscan2
- IGHV2-70D | c.315C>T p.N105= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, varscan2
- IGHV2-70D | c.186A>T p.P62= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, varscan2
- IGLL5 | c.63G>A p.R21= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs6003367, COSV101597229; called by muse, varscan2
- IGLV3-1 | c.72T>C p.T24= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs191429645; called by muse, varscan2
- KIAA0895L | c.1147C>T p.L383= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- LRP1 | c.3903C>T p.A1301= | Silent (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- MROH2A | c.3990G>A p.V1330= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.2367T>C p.A789= | Silent (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- PHACTR2 | c.18C>T p.D6= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs780280940; called by muse, mutect2, varscan2
- PSME4 | c.435T>G p.L145= | Silent (SNP) | VAF 50/92 reads (54%) | called by muse, mutect2, varscan2
- PTPRB | c.129C>A p.I43= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- REXO1 | c.2448C>T p.V816= | Silent (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- TDRD12 | c.936T>C p.H312= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1568469465; called by muse, mutect2, varscan2
- TTC30B | c.453G>A p.E151= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV68809563; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154246 C>T | 3'Flank (SNP) | VAF 10/71 reads (14%) | catalogued as rs368254032; called by muse, mutect2, varscan2
- AC113208.3 | n.1587A>G | RNA (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1459A>G | Intron (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- ADRA2A | c.-73G>T | 5'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- ARHGAP8 | c.80-126G>A | Intron (SNP) | VAF 13/30 reads (43%) | catalogued as rs561786895; called by muse, mutect2, varscan2
- ATAD2B | c.*58dup | 3'UTR (INS) | VAF 12/158 reads (8%) | called by mutect2, pindel
- BATF2 | chr11:64996994 T>C | 5'Flank (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- BBS1 | c.47+13C>A | Intron (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021150 A>G | 5'Flank (SNP) | VAF 53/89 reads (60%) | catalogued as COSV55847065, COSV55851768; called by muse, mutect2, varscan2
- BCL7A | chr12:122021371 A>C | 5'Flank (SNP) | VAF 30/96 reads (31%) | catalogued as rs1047978703; called by muse, mutect2, varscan2
- BCL7A | c.*1744dup | 3'UTR (INS) | VAF 9/91 reads (10%) | catalogued as rs1223836111; called by pindel, varscan2*
- BIRC3 | c.*172T>G | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- C11orf24 | c.*53G>A | 3'UTR (SNP) | VAF 72/158 reads (46%) | called by muse, mutect2, varscan2
- CDC42BPB | c.*249T>C | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- CDK19 | c.*3688dup | 3'UTR (INS) | VAF 11/35 reads (31%) | catalogued as rs961151641; called by mutect2, varscan2
- CHID1 | c.*670G>A | 3'UTR (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
- CLTC | c.*1033G>A | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- CNTN5 | c.2730+452A>C | Intron (SNP) | VAF 37/62 reads (60%) | catalogued as rs1336620074; called by muse, mutect2, varscan2
- CPPED1 | c.*509G>C | 3'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- CRYL1 | c.633+13G>A | Intron (SNP) | VAF 36/74 reads (49%) | catalogued as rs367813839; called by muse, mutect2, varscan2
- CSMD3 | c.9863-49C>G | Intron (SNP) | VAF 25/55 reads (45%) | catalogued as rs768564975; called by muse, mutect2, varscan2
- CYFIP1 | c.3043-134del | Intron (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- ELOVL6 | c.*828C>T | 3'UTR (SNP) | VAF 10/14 reads (71%) | catalogued as rs747696597, COSV56429127; called by muse, varscan2
- FEM1B | c.*674C>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- FER | c.*4569C>A | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- FGA | c.1891+187_1891+190del | Intron (DEL) | VAF 32/66 reads (48%) | called by pindel, varscan2
- GALNT17 | c.*211A>G | 3'UTR (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-4533C>T | Intron (SNP) | VAF 75/160 reads (47%) | catalogued as rs1426779482; called by muse, mutect2, varscan2
- GTF2F2 | c.*240A>C | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- HSD17B11 | c.-95A>C | 5'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- IGLL5 | c.-11C>T | 5'UTR (SNP) | VAF 28/76 reads (37%) | catalogued as rs528299670, COSV73249616, COSV73251126; called by muse, varscan2
- IMPA2 | c.-156C>G | 5'UTR (SNP) | VAF 21/33 reads (64%) | catalogued as COSV52318823; called by muse, mutect2, varscan2
- ITGA4 | c.556+710dup | Intron (INS) | VAF 52/60 reads (87%) | catalogued as rs397870246; called by mutect2, varscan2
- KANK1 | c.3006-187G>C | Intron (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- KCNC2 | c.*886_*887del | 3'UTR (DEL) | VAF 72/140 reads (51%) | catalogued as rs1299230378, COSV54383189; called by pindel, varscan2*
- KLF12 | c.*7740T>C | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- LAMTOR3 | c.*2455del | 3'UTR (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- LPP | c.*5880C>G | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- LUC7L3 | chr17:50754202 C>G | 3'Flank (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- MARCKS | c.*2448dup | 3'UTR (INS) | VAF 7/18 reads (39%) | called by mutect2, pindel
- MFN1 | c.*58C>A | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851350 C>T | 5'Flank (SNP) | VAF 36/74 reads (49%) | called by muse, varscan2
- MROH2B | c.1502-65G>A | Intron (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- NR1D2 | c.-130G>A | 5'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2
- NRSN1 | c.*237G>A | 3'UTR (SNP) | VAF 50/107 reads (47%) | catalogued as rs747104265; called by muse, mutect2, varscan2
- OBSCN | c.11660-1006C>A | Intron (SNP) | VAF 32/107 reads (30%) | catalogued as COSV99479344; called by muse, mutect2, varscan2
- OR3A4P | n.938G>A | RNA (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- PAXX | c.119+39C>G | Intron (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- PCNX3 | c.-202G>A | 5'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- PDXDC1 | c.*623C>T | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- PEX5L | c.*609A>C | 3'UTR (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- POU4F1 | c.-14G>T | 5'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- PTK2 | c.*103C>T | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, varscan2
- RASAL1 | c.*310A>T | 3'UTR (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- RPL10 | c.82+13A>C | Intron (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- S100PBP | c.*228C>T | 3'UTR (SNP) | VAF 27/52 reads (52%) | catalogued as rs1212903968; called by muse, mutect2, varscan2
- SDK1 | c.*2906T>G | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- SELL | c.1120+27A>G | Intron (SNP) | VAF 56/87 reads (64%) | called by muse, mutect2, varscan2
- SLC22A2 | n.670T>C | RNA (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- SLC2A13 | c.*1263T>G | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- SND1 | c.1455-33G>C | Intron (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- TFAP4 | c.-106del | 5'UTR (DEL) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- TRARG1 | c.*1071G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs545989942; called by muse, mutect2, varscan2
- TRIM24 | c.*2385G>C | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141446522 C>T | 3'Flank (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.*1209A>T | 3'UTR (SNP) | VAF 63/91 reads (69%) | called by muse, mutect2, varscan2
- ZGLP1 | c.-1167G>T | 5'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- ZGRF1 | c.102+3126G>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
